Surgical pathology report (de-identified scan), TCGA case TCGA-Y6-A8TL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Arizona, specimen TCGA-Y6-A8TL-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

Hospital #
Patient Name:

Birthdate:
Visit #:
Date Collected:
Requesting Physician:

(Age:

Gender: M
Location:
Received:

Medical Director

SURGICAL PATHOLOGY REPORT

ACCESSION NO.

Final Diagnosis(es):

(A) Prostate, radical prostatectomy:

- 1) Prostatic adenocarcinoma, Gleason sum score 3+3=6.
- 2) Tumor size (dominant nodule) 1.5 x 1.0 x 1.0 cm; 1.5 cm³.
- 3) Primary tumor in right apex with capsular penetration, focal (slide A2).
- 4) Positive surgical margin in right posterior apex (slide A3).
- 5) Pathologic stage pT3aN0MX.
- 6) See Synoptic report.

(B) Lymph nodes, bilateral pelvic, excision: Five lymph nodes negative for metastasis.

Synoptic Report:

Diagnosis: Prostatic adenocarcinoma.
Procedure: Radical prostatectomy.
Specimen Size: 4.4 x 3.7 x 3.3 cm.
Specimen Weight: 24 gm
Lymph Node Sampling: Pelvic lymph node dissection.
Histologic Type: Adenocarcinoma, acinar type.
Histologic Grade (Gleason pattern)
Primary Pattern: Grade 3
Secondary Pattern: Grade 3
Total Gleason Score: 6
Percent of Prostate Involved: 6.2%
Size of Dominant Nodule
Greatest dimension: 15 mm
Additional dimensions: 10 x 10 mm
Extraprostatic Extension: Focal.
Seminal Vesicle Invasion:
Left: Negative.
Right: Negative.
Lymphovascular Invasion: Negative.
Margins:
Apical: Positive, right posterior.
Bladder neck: Negative.
Anterior: Negative.

1400 3
Adenocarcinoma NOS 814013
Site: Prostate NOS C61.9
J 5/20/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Lateral: Negative.
Posterolateral: Negative.
Posterior: Negative.
Nodes: Node Group: Pelvic, bilateral.
Total: 5
Positive: 0
Pathologic Stage: pT3aNOMX.

Electronically Signed

Specimen(s) Received:

A: Prostate with seminal vesicles
B: Bilateral pelvic lymph nodes

Clinical History:

Prostate cancer.
(A) Tumor Bank.

-

Gross Description:

(A) (prostate and seminal vesicles) Received in formalin is a radical prostatectomy that has been previously inked, sectioned and sampled by Tumor Bank. The capsule appears intact, is slightly ragged and the specimen measures 3.3 cm superior to inferior, 4.4 cm right to left, and 3.7 cm anterior to posterior. With the bilateral seminal vesicles removed, the prostate weighs 24 gm. The right seminal vesicle measures 2.0 x 1.6 x 0.7 cm and the right vas deferens measures 3.4 cm in length x 1.1 cm in diameter. The left seminal vesicle measures 2.8 x 1.4 x 0.8 cm and the left vas deferens measures 4.7 cm in length x 0.7 cm in diameter. The right half is inked red, the left half is inked green and the posterior midline is inked black. The specimen is sectioned and shows multifocal pale tan firm lesions within the right posterior base, comprising roughly 5% of the total volume of the specimen. The remaining volume consists of tan-pink rubbery trabeculated tissue. The apical/distal margin is serially sagittally sectioned and submitted entirely in sequence from right to left in A1-A7. The remaining prostate is entirely submitted in sequence from distal to proximal in A8-A25. Bilateral seminal vesicles/segments of vas deferens are entirely submitted in sequence from distal to proximal in A26-A39. A diagram facilitates orientation.

(B) (bilateral pelvic lymph nodes) Received in formalin is a collection of tan-pink to yellow soft to rubbery lobular fibroadipose tissue that measures 3.6 x 3.0 x 1.5 cm in aggregate. Dissection and palpation yield five tan-pink rubbery lymph nodes measuring from 1.1 to 3.0 cm in greatest dimension. Specimens are submitted as follows:

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

- B1 - largest lymph node, serially sectioned, submitted entirely
- B2 - next largest lymph node, similarly sectioned and submitted entirely
- B3 - the three smaller lymph nodes, submitted intact

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the manufacturer. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EGFR(31G7), ER(8F11), PR(p18), Her2neu(CB11), CD117(Poly), CD20(L28).

Unless otherwise stated in the report, all tissue tested for HER2 by IHC and/or HER2 by FISH have been fixed as per ANP.22898 for a minimum of 8 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Final Report
Printed

Page 3 of 3

Source: NCI Genomic Data Commons file e40f3989-94eb-47a5-86b7-dab354fafcf8 (TCGA-Y6-A8TL.8DE4AB1E-913E-4763-81EE-272430E5CC4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).